Somatic mutation profile of tumor specimen 0DITT6 from CCDI case PBBVZV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; Age at diagnosis: 17.0 years (6,220 days).
Specimen 0DITT6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b8cff6ea-37bc-42ca-ab18-6db29388777b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DITSE (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9abfbfc3-d50b-4808-94b4-fd85efd3d80a

The open-access MAF lists 121 somatic variants for this specimen: 75 protein-altering or splice-affecting, 27 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 65, Silent 27, Intron 10, Nonsense Mutation 6, 3'UTR 6, 5'Flank 1, Frame Shift Ins 1, In Frame Del 1, 5'UTR 1, RNA 1, In Frame Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- STXBP2 | c.1214G>A p.R405Q | Missense Mutation (SNP) | VAF 42/383 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs773360200, CM096294, COSV55405123; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.517G>A p.V173M | Missense Mutation (SNP) | VAF 149/363 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as rs876660754, CM070299, COSV52676535, COSV52677795, COSV52695723, COSV52823354; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB1 | c.2744A>G p.K915R | Missense Mutation (SNP) | VAF 148/4508 reads (3%) | SIFT tolerated (0.4); PolyPhen benign (0.14); catalogued as COSV55945450, COSV55964424; called by muse, mutect2
- ABCB1 | c.2614G>T p.G872* | Nonsense Mutation (SNP) | VAF 179/4386 reads (4%) | catalogued as COSV55962757; called by muse, mutect2
- ABCF1 | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 48/402 reads (12%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs767397757, COSV58228252; called by muse, varscan2
- ACTL9 | c.1231G>A p.V411M | Missense Mutation (SNP) | VAF 55/178 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs782060616, COSV61005266; called by muse, mutect2, varscan2
- AGO2 | c.1283C>T p.A428V | Missense Mutation (SNP) | VAF 40/229 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs764026573; called by muse, varscan2
- ATP13A2 | c.3068C>T p.T1023I | Missense Mutation (SNP) | VAF 32/223 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV58702371; called by muse, mutect2, varscan2
- CCKAR | c.1037G>A p.R346H | Missense Mutation (SNP) | VAF 85/473 reads (18%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs774446786; called by muse, mutect2, varscan2
- CLDN18 | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 71/551 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); catalogued as COSV59302948; called by muse, mutect2, varscan2
- CMIP | c.407G>C p.G136A (on ENST00000537098 / NM_198390.2; = p.G42A on NM_030629.3) | Missense Mutation (SNP) | VAF 74/466 reads (16%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.991); catalogued as COSV73344997; called by muse, mutect2, varscan2
- DRD1 | c.130G>A p.V44I | Missense Mutation (SNP) | VAF 151/444 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV101192546; called by muse, mutect2, varscan2
- FAT3 | c.12035C>T p.T4012M | Missense Mutation (SNP) | VAF 55/397 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.967); catalogued as COSV99968206; called by muse, mutect2, varscan2
- FPR3 | c.713G>A p.R238H | Missense Mutation (SNP) | VAF 161/644 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.258); catalogued as rs764805147, COSV59330276; called by muse, mutect2, varscan2
- GGT1 | c.295C>T p.R99* | Nonsense Mutation (SNP) | VAF 136/275 reads (49%) | catalogued as rs753103118; called by muse, mutect2, varscan2
- IRS4 | c.3725A>T p.D1242V | Missense Mutation (SNP) | VAF 181/529 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.834); catalogued as rs1484592236; called by muse, mutect2, varscan2
- KCNG1 | c.1040C>T p.A347V | Missense Mutation (SNP) | VAF 66/276 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV65368486; called by muse, mutect2, varscan2
- KLHDC3 | c.922G>T p.G308C | Missense Mutation (SNP) | VAF 22/505 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV55063797; called by muse, mutect2
- LYST | c.10964C>T p.A3655V | Missense Mutation (SNP) | VAF 146/505 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as rs957215716, COSV67707617; called by muse, mutect2, varscan2
- MAP2K2 | c.691C>T p.R231C | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375843855; called by muse, mutect2, varscan2
- MDN1 | c.535C>T p.H179Y | Missense Mutation (SNP) | VAF 73/441 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.474); catalogued as rs1211431395; called by muse, mutect2, varscan2
- MYO15A | c.4072G>A p.G1358S | Missense Mutation (SNP) | VAF 76/932 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1291982378, CM153985; called by muse, mutect2
- MYO15B | c.6310C>A p.P2104T | Missense Mutation (SNP) | VAF 167/344 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.684); catalogued as rs192928339; called by muse, mutect2, varscan2
- OBSL1 | c.2861G>A p.R954H | Missense Mutation (SNP) | VAF 51/408 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs771774642; called by muse, mutect2, varscan2
- OGDHL | c.2869C>T p.P957S | Missense Mutation (SNP) | VAF 114/360 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs775448655; called by muse, mutect2, varscan2
- OR10G7 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 74/639 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs769686295, COSV57867194; called by muse, mutect2, varscan2
- OR10G9 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 57/391 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755974430; called by muse, mutect2
- OR10X1 | c.439A>T p.R147* | Nonsense Mutation (SNP) | VAF 152/652 reads (23%) | catalogued as COSV63766856, COSV63768053; called by muse, varscan2
- OR3A1 | c.190T>G p.F64V | Missense Mutation (SNP) | VAF 44/293 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); catalogued as COSV60162431; called by muse, mutect2, varscan2
- PCDHA11 | c.1438G>A p.D480N | Missense Mutation (SNP) | VAF 51/331 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100253417; called by muse, mutect2, varscan2
- PCLO | c.8192G>A p.R2731H | Missense Mutation (SNP) | VAF 102/1997 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs200140697, COSV61622195; called by muse, mutect2
- RIT2 | c.154A>G p.T52A | Missense Mutation (SNP) | VAF 114/506 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1430955035; called by muse, mutect2, varscan2
- USE1 | c.384G>A p.T128= | Splice Region (SNP) | VAF 88/308 reads (29%) | catalogued as rs781274976; called by muse, mutect2, varscan2
- ABCC9 | c.3456C>G p.Y1152* | Nonsense Mutation (SNP) | VAF 227/825 reads (28%) | called by muse, mutect2, varscan2
- ADGRG4 | c.3979A>C p.N1327H | Missense Mutation (SNP) | VAF 123/826 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- ANAPC7 | c.1168_1173dup p.Q390_E391dup | In Frame Ins (INS) | VAF 128/479 reads (27%) | called by mutect2, varscan2
- BRD7 | c.401C>T p.T134I | Missense Mutation (SNP) | VAF 67/745 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); called by muse, mutect2
- C9orf85 | c.40C>T p.Q14* | Nonsense Mutation (SNP) | VAF 97/559 reads (17%) | called by muse, varscan2
- CCDC50 | c.1429G>C p.G477R (on ENST00000392455 / NM_178335.3; = p.G301R on NM_174908.4) | Missense Mutation (SNP) | VAF 141/914 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCL4 | c.173G>T p.C58F | Missense Mutation (SNP) | VAF 61/586 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CDYL | c.1742C>G p.A581G (on ENST00000328908 / NM_001368125.1; = p.A527G on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 69/671 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- CLUAP1 | c.1238T>C p.F413S | Missense Mutation (SNP) | VAF 90/308 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, varscan2
- CNTNAP3B | c.665T>G p.L222R | Missense Mutation (SNP) | VAF 120/1735 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- COL4A1 | c.1190G>T p.G397V | Missense Mutation (SNP) | VAF 70/1286 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CYP7B1 | c.659A>T p.D220V | Missense Mutation (SNP) | VAF 391/1039 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DCP1A | c.391C>T p.R131W | Missense Mutation (SNP) | VAF 100/565 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- DENND4B | c.2111A>C p.D704A | Missense Mutation (SNP) | VAF 31/253 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- EEF1A2 | c.1309G>A p.V437I | Missense Mutation (SNP) | VAF 58/477 reads (12%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- FASN | c.5360A>G p.K1787R | Missense Mutation (SNP) | VAF 26/330 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.255); called by muse, mutect2
- H2BC11 | c.209T>A p.I70N | Missense Mutation (SNP) | VAF 57/596 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- HLTF | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 56/1324 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- INSRR | c.412G>T p.A138S | Missense Mutation (SNP) | VAF 74/382 reads (19%) | SIFT tolerated (0.61); PolyPhen benign (0.114); called by muse, varscan2
- IRX1 | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 141/287 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- LAMC3 | c.2834A>T p.Q945L | Missense Mutation (SNP) | VAF 14/358 reads (4%) | SIFT tolerated (0.48); PolyPhen benign (0.009); called by muse, mutect2
- LFNG | c.1045C>T p.P349S (on ENST00000222725 / NM_001040167.2; = p.P220S on NM_002304.2) | Missense Mutation (SNP) | VAF 61/639 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.06); called by muse, mutect2
- MBD3L1 | c.499A>T p.R167* | Nonsense Mutation (SNP) | VAF 68/418 reads (16%) | called by muse, mutect2, varscan2
- MFSD4A | c.58A>G p.T20A | Missense Mutation (SNP) | VAF 63/175 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- MOCOS | c.1051A>G p.T351A | Missense Mutation (SNP) | VAF 15/298 reads (5%) | SIFT tolerated (0.77); PolyPhen benign (0.006); called by muse, mutect2
- MUC5AC | c.3876C>G p.H1292Q | Missense Mutation (SNP) | VAF 44/440 reads (10%) | SIFT deleterious (0.01); called by muse, mutect2
- NBEAL2 | c.1000dup p.E334Gfs*25 | Frame Shift Ins (INS) | VAF 74/394 reads (19%) | called by mutect2, varscan2
- NOL9 | c.1121A>G p.Y374C | Missense Mutation (SNP) | VAF 147/349 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- OR2D2 | c.799C>G p.Q267E | Missense Mutation (SNP) | VAF 86/865 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRDM1 | c.2360C>T p.S787L | Missense Mutation (SNP) | VAF 46/466 reads (10%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.983); called by muse, mutect2
- RALGPS2 | c.977C>T p.T326I | Missense Mutation (SNP) | VAF 100/1222 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.542); called by muse, mutect2
- RAPGEF5 | c.547_549del p.V183del (on ENST00000401957 / NM_001367602.2; = p.V486del on NM_012294.5) | In Frame Del (DEL) | VAF 70/660 reads (11%) | called by mutect2, varscan2
- SEZ6L2 | c.155C>A p.A52D | Missense Mutation (SNP) | VAF 80/458 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- SLC32A1 | c.181G>T p.D61Y | Missense Mutation (SNP) | VAF 156/787 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- SLC35D2 | c.259G>C p.D87H | Missense Mutation (SNP) | VAF 59/430 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- STK4 | c.371A>G p.D124G | Missense Mutation (SNP) | VAF 60/736 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.185); called by muse, mutect2
- TEKT3 | c.1345G>A p.V449I | Missense Mutation (SNP) | VAF 79/563 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- TOP3A | c.1627G>A p.E543K | Missense Mutation (SNP) | VAF 82/486 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TRIM51GP | c.1282A>C p.S428R | Missense Mutation (SNP) | VAF 98/874 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- UBASH3A | c.1454G>T p.R485L | Missense Mutation (SNP) | VAF 79/482 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- USP20 | c.1492G>A p.A498T | Missense Mutation (SNP) | VAF 45/318 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- ZDHHC8 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 28/328 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- BACH2 | c.510G>A p.T170= | Silent (SNP) | VAF 85/439 reads (19%) | catalogued as rs374825480, COSV57611007; called by muse, mutect2, varscan2
- CACNA1A | c.5511C>T p.Y1837= | Silent (SNP) | VAF 81/601 reads (13%) | catalogued as rs777510892, COSV64207391; called by muse, mutect2, varscan2
- CCDC120 | c.1887T>C p.F629= | Silent (SNP) | VAF 88/376 reads (23%) | called by muse, mutect2, varscan2
- CDKL4 | c.417A>T p.I139= | Silent (SNP) | VAF 55/485 reads (11%) | called by muse, mutect2, varscan2
- DOCK7 | c.72C>T p.S24= | Silent (SNP) | VAF 176/721 reads (24%) | catalogued as rs369563931; ClinVar: likely benign; called by muse, mutect2, varscan2
- FOXR2 | c.732C>A p.L244= | Silent (SNP) | VAF 193/913 reads (21%) | called by muse, mutect2, varscan2
- GFRA3 | c.771C>T p.S257= | Silent (SNP) | VAF 63/356 reads (18%) | catalogued as rs755778200; called by muse, mutect2, varscan2
- KIAA0825 | c.1152T>C p.D384= | Silent (SNP) | VAF 117/683 reads (17%) | called by muse, mutect2, varscan2
- LHFPL6 | c.447G>T p.R149= | Silent (SNP) | VAF 94/621 reads (15%) | catalogued as COSV65446820; called by muse, mutect2, varscan2
- LORICRIN | c.447C>T p.G149= | Silent (SNP) | VAF 46/674 reads (7%) | catalogued as rs992588213; called by muse, mutect2
- MAP2K5 | c.708G>A p.R236= | Silent (SNP) | VAF 62/518 reads (12%) | called by muse, varscan2
- MARCHF4 | c.150G>A p.K50= | Silent (SNP) | VAF 41/245 reads (17%) | catalogued as COSV56106526; called by muse, mutect2, varscan2
- MUC22 | c.1608C>T p.T536= | Silent (SNP) | VAF 43/186 reads (23%) | catalogued as rs1055254538; called by muse, mutect2, varscan2
- NIPBL | c.1173T>C p.P391= | Silent (SNP) | VAF 476/1059 reads (45%) | called by muse, mutect2, varscan2
- OR10X1 | c.477A>G p.Q159= | Silent (SNP) | VAF 181/801 reads (23%) | catalogued as COSV63767884; called by muse, varscan2
- PRAMEF19 | c.1029G>T p.L343= | Silent (SNP) | VAF 75/549 reads (14%) | called by muse, mutect2, varscan2
- SCN7A | c.630T>G p.T210= | Silent (SNP) | VAF 133/1151 reads (12%) | catalogued as COSV69270544, COSV69270710; called by muse, mutect2, varscan2
- SEMA3A | c.1797G>A p.P599= | Silent (SNP) | VAF 1192/2042 reads (58%) | catalogued as rs367617715; called by muse, varscan2
- SIM1 | c.1989G>C p.S663= | Silent (SNP) | VAF 67/552 reads (12%) | called by muse, mutect2, varscan2
- SLC35G3 | c.327G>T p.L109= | Silent (SNP) | VAF 56/375 reads (15%) | called by muse, mutect2, varscan2
- SLCO1B1 | c.657T>A p.G219= | Silent (SNP) | VAF 42/1433 reads (3%) | called by muse, mutect2
- SMG6 | c.561G>A p.A187= | Silent (SNP) | VAF 135/487 reads (28%) | catalogued as rs767800204; called by muse, mutect2, varscan2
- SPATA17 | c.888T>G p.S296= | Silent (SNP) | VAF 188/785 reads (24%) | catalogued as COSV65125776; called by muse, mutect2, varscan2
- SPTBN5 | c.5157G>A p.A1719= | Silent (SNP) | VAF 48/324 reads (15%) | catalogued as rs376418222; called by muse, mutect2, varscan2
- TBL1XR1 | c.684C>A p.V228= | Silent (SNP) | VAF 56/524 reads (11%) | called by muse, varscan2
- TEX47 | c.651G>A p.L217= | Silent (SNP) | VAF 280/4342 reads (6%) | catalogued as COSV99787191; called by muse, mutect2
- WWOX | c.414C>T p.F138= | Silent (SNP) | VAF 223/640 reads (35%) | catalogued as rs767693780, COSV63435279; ClinVar: likely benign; called by muse, mutect2, varscan2
- AC139769.1 | n.214-4356G>A | Intron (SNP) | VAF 35/560 reads (6%) | called by muse, mutect2
- B4GALNT1 | c.712+254C>G | Intron (SNP) | VAF 97/285 reads (34%) | catalogued as rs1485084709; called by muse, mutect2, varscan2
- CEMIP2 | c.2592-79T>G | Intron (SNP) | VAF 18/95 reads (19%) | called by muse, mutect2, varscan2
- CEP126 | c.*37C>T | 3'UTR (SNP) | VAF 77/372 reads (21%) | called by muse, mutect2, varscan2
- CHCHD7 | c.*78C>A | 3'UTR (SNP) | VAF 43/124 reads (35%) | called by muse, mutect2, varscan2
- ELOBP3 | chr2:48776331 A>C | 5'Flank (SNP) | VAF 301/748 reads (40%) | called by muse, mutect2, varscan2
- EML6 | c.*100C>T | 3'UTR (SNP) | VAF 203/461 reads (44%) | catalogued as COSV58272015; called by muse, mutect2, varscan2
- GCNT2 | c.926-34526G>A | Intron (SNP) | VAF 138/599 reads (23%) | catalogued as rs374501897; called by muse, mutect2, varscan2
- INHBA | c.*27G>A | 3'UTR (SNP) | VAF 50/343 reads (15%) | catalogued as rs1167101493; called by muse, mutect2, varscan2
- KRTAP5-9 | c.*27T>A | 3'UTR (SNP) | VAF 14/144 reads (10%) | called by muse, mutect2
- MUC19 | n.5128C>T | RNA (SNP) | VAF 211/896 reads (24%) | catalogued as rs1036464810; called by muse, mutect2, varscan2
- NIPBL | c.6955-84C>G | Intron (SNP) | VAF 10/142 reads (7%) | called by muse, mutect2
- PABPC1 | c.194-66A>T | Intron (SNP) | VAF 83/210 reads (40%) | called by muse, mutect2, varscan2
- RASGEF1C | c.301-67C>T | Intron (SNP) | VAF 16/180 reads (9%) | catalogued as rs988796665, COSV63179448; called by muse, mutect2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 34/244 reads (14%) | called by muse, varscan2
- RPUSD3 | c.407+41C>T | Intron (SNP) | VAF 21/196 reads (11%) | catalogued as rs1393503890; called by muse, mutect2, varscan2
- SLC19A1 | c.*663C>T | 3'UTR (SNP) | VAF 39/324 reads (12%) | called by muse, mutect2, varscan2
- SNX2 | c.1357-36del | Intron (DEL) | VAF 32/172 reads (19%) | catalogued as rs772622695; called by mutect2, varscan2
- YAF2 | c.152+26951G>T | Intron (SNP) | VAF 34/460 reads (7%) | catalogued as rs1041371904, COSV100586253; called by muse, mutect2
